Surgical pathology report (de-identified scan), TCGA case TCGA-AF-3913, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-AF-3913-01A (Primary Tumor).

[page 1 of 6]
SPECIMEN

- A. Right pelvic lymph nodes grossly suspicious only
- B. Left pelvic lymph nodes grossly suspicious only
- C. Prostate
- D. Splenic flexure colon
- E. Recto-sigmoid colon
- F. Appendix

CLINICAL NOTES

PRE-OP DIAGNOSIS: Cancer of the rectum and prostate.

FROZEN SECTION DIAGNOSIS

- FSA) No frozen section done.
- FSB) No frozen section done.

GROSS DESCRIPTION

A. Is submitted fresh for possible frozen, labeled "right pelvic lymph nodes". It consists of a 6 x 4 x 2 cm. portion of lymph node-bearing fat, which contains numerous steel clips. The section of the fat reveals the presence of five suspected lymph nodes. The smallest of these is 5 mm. in size, the largest 3 cm. Bisecting all of the lymph nodes shows them to be made up of soft fleshy reddish-brown tissue without grossly suspicious areas of metastasis, therefore no frozen sections are performed as per request of Dr. [REDACTED]
BLOCK SUMMARY: Block [**09-30**] - Quadrisected lymph node, [**09-30**] in each cassette; blocks 5,6 - bisected lymph node, half in each cassette; block 7 - two additional lymph nodes. RS-7.

B. Is submitted fresh, labeled "left pelvic nodes" and consists of a 3 x 3 x 2 cm. mass of lymph node-bearing fat.

The section of fat reveals a large single lymph node present, measuring 4 x 2 x 1 cm. Bisecting the node shows it to be soft, without evidence of any firm or suspicious areas. Therefore, no

GROSS DESCRIPTION

frozen section is done per request of Dr. [REDACTED]
[**]. The single node is bisected, half submitted in each cassette. RS-2.

C. Received fresh, subsequently fixed in formalin, labeled "prostate" is a 28 gm prostate. This has an inserted catheter and the prostate, itself, is 4.5 x 3.5 x 3.2 cm. This has attached bilateral adnexa. The seminal vesicles average 2.2 x 1 x 0.7 cm and the vasa deferentia average 2.2 x 0.5 cm. The right side is inked blue and the left side is inked black. The adnexa is amputated from the specimen and the apical and bladder margins are coned from the

[page 2 of 6]
specimen. The remainder of the specimen is sectioned from apex to base to show a pink-tan rubbery and nodular cut surface with no other discrete gross lesions identified. Representative sections of the specimen which include the entire prostate are submitted as follows: Block 1 - apical margin; block 2 - bladder margin; blocks 3, 4 - slice 1 full thickness composite; blocks 5, 6 - slice 2 full thickness composite; blocks 7, 8 - slice 3 full thickness composite; blocks 9, 10 - slice 4 full thickness composite; blocks 11, 12 - slice 5 full thickness composite; blocks 13, 14 - slice 6 full thickness composite; block 15 - last slice, slice 7, bisected full thickness composite; block 16 - base of adnexa and possible vas deferential margin. RS-16 (entire prostate submitted).

D. Received fresh, subsequently fixed in formalin, labeled "splenic flexure colon." The specimen consists of a 7 cm long portion of colon which is stapled at both ends. The ends of the specimen are arbitrarily inked blue and black. The serosa is pink-tan smooth glistening and the specimen is partially covered with fat. The specimen is previously opened to show a pink-tan smooth glistening mucosa, having a circumference of 8.5 cm. There is a large exophytic mass measuring 4 x 3.2 x 2.2 cm. This is located equidistant in the specimen. There are two additional small

polyps grossly identified in the mucosa which are 0.2 cm and 0.3 cm in greatest dimension. The smaller is located 2 cm from the nearest luminal margin (inked black) and the larger is located 1.5 cm from

GROSS DESCRIPTION

the tumor located equidistant between both luminal margins. Lymph nodes are grossly identified in fat. The cut surface of the tumor shows minimal invasion into the muscularis propria, not through the muscularis propria, and comes within 1.5 cm of the deep more radial margin. Representative sections of the specimen are as follows: BLOCK SUMMARY: Block 1 - Representative luminal margins; block 2 - small polyp; blocks [**11-30**] - representative sections of tumor to normal and radial margin; block 6 - has two possible lymph nodes. RS-6.

E. Received fresh, subsequently fixed in formalin, labeled

"rectum and sigmoid." The specimen consists of a rectosigmoid colon which is 13 cm long. The specimen is opened at one end (inked blue) and at the opposite end is stapled. The stapled end is inked black. The specimen is partially covered with pink-tan, smooth glistening serosa and yellow lobular fat. The

[page 3 of 6]
retroperitoneal reflection is located 5 cm from the black inked end. The specimen is opened to show a pink-tan smooth glistening mucosa with an average circumference of 7 cm. There is a large exophytic mass which is 5.5 x 3.5 x 1.2 cm located 2.5 cm from the distal margin. There are additional small polyps which range from 0.5 cm to 1 cm. These are located within 0.5 cm of the blue-inked end to

5

cm of the black inked end. The cut surface of the small polyps shows no discrete invasions of muscularis propria. The cut surface has a large mass and shows invasion through the muscularis propria and comes within 2.5 cm of the radial margin. Lymph nodes are grossly identified in the fat. Representative sections of the specimen are as follows:

BLOCK SUMMARY: Block 1 - representative luminal margins which include small polyp at proximal end; blocks 2, 3 - additional polyps; blocks [**01-01**] - tumor to normal and deep; block 7 - representative radial margin; blocks 8, 9 - have nine possible lymph nodes each; block 10 - has five possible lymph nodes; block 11 - has four possible lymph nodes; block 12 - has one possible lymph node

GROSS DESCRIPTION

bisected. RS-12.

F. Received in formalin labeled "appendix" is a grossly unremarkable appendix, partially covered with yellow lobular fat and pink-tan smooth glistening serosa. The specimen is 6.5 x 0.5 cm. The specimen is sectioned to show an intact wall with

an average thickness of 0.4 cm. The lumen ranges from pinpoint to 0.3 cm. No other discrete gross lesions are identified. Representative sections of the specimen are submitted in one cassette with the proximal end inked. RS-1.

MICROSCOPIC DESCRIPTION

A-C: Prostate, seminal vesicles, and bilateral pelvic nodes -

Histologic type: Adenocarcinoma, NOS.

Histologic (Gleason) grade: 7 (3+4).

Primary tumor (pT): Tumor involves the left lobe of the prostate gland and exhibits extraprostatic extension (pT3a).

Extraprostatic extension: Present.

Seminal vesicle invasion: Negative.

Margins of resection: Negative.

Regional lymph nodes (pN): Right and left pelvic nodes are negative for metastatic carcinoma (pN0).

[page 4 of 6]
Distant metastasis (pM): Cannot be assessed (pMx).
Vascular invasion: Negative.
Other findings: Perineural invasion by tumor is present.

D. Splenic flexure colon -

Histologic type: Adenocarcinoma.
Histologic grade: Moderately-differentiated.
Primary tumor (pT): Tumor has invaded into, but not through, the

MICROSCOPIC DESCRIPTION

muscularis propria (pT2).
Proximal margin: Negative.
Distal margin: Negative.
Circumferential (radial) margin: Negative.
Vascular invasion: Negative.
Regional lymph nodes (pN): Two mesenteric lymph nodes are negative for metastatic carcinoma (pN0).
Non-lymph node pericolic tumor: Absent.
Distant metastasis (pM): Cannot be assessed (pMx).
Other findings: The tumor has arisen in a tubulovillous adenoma.
Hyperplastic polyp.

E. Rectosigmoid colon -

Histologic type: Adenocarcinoma.
Histologic grade: Moderately-differentiated.
Primary tumor (pT): The tumor has extended through the muscularis propria into the pericolic fat (pT3).
Proximal margin: Negative.
Distal margin: Negative.
Circumferential (radial) margin: Negative.
Vascular invasion: Negative.
Regional lymph nodes (pN): One of 26 mesenteric lymph nodes contains metastatic adenocarcinoma (pN1a).
Non-lymph node pericolic tumor: Absent.
Distant metastasis (pM): Cannot be assessed (pMx).
Other findings: 6 hyperplastic polyps.

5x3, 4, 3, 1, 13x2

[page 5 of 6]
DIAGNOSIS

- A. Lymph nodes, right pelvic resection:
Four lymph nodes negative for metastatic carcinoma (0/4).

DIAGNOSIS

- B. Lymph node, left pelvic, resection:
Single lymph node negative for metastatic carcinoma (0/1).
- C. Prostate and seminal vesicles, resection:
Invasive moderate to poorly-differentiated prostatic adenocarcinoma, Gleason's grade 7 (3+4) involving the left lobe of the prostate gland. Extraprostatic extension is present.
The apex, bladder neck, and capsular margin of resection are free of involvement by tumor.
Seminal vesicles negative for involvement by tumor.
Perineural invasion by tumor is present.
- D. Colon, splenic flexure, segmental resection:
Invasive moderately-differentiated adenocarcinoma arising in
a tubulovillous adenoma.
Carcinoma has extended into, but not through, the muscularis propria. Proximal, distal and radial margins of resection free of tumor.
Two mesenteric lymph nodes negative for metastatic carcinoma (0/2). Hyperplastic polyp.
- E. Colon, rectosigmoid, segmental resection:
Invasive moderately-differentiated colonic adenocarcinoma extending through the wall of the colon into the serosal fat.

Proximal, distal and radial margins of resection are free of tumor.
One of 26 mesenteric lymph nodes contains metastatic adenocarcinoma.

Six hyperplastic polyps.

[page 6 of 6]
DIAGNOSIS

F. Appendix, incidental appendectomy:
No significant histopathologic findings.

3

--- End Of Report ---

Source: NCI Genomic Data Commons file 68737689-99b8-448d-baca-cf75b31063d3 (TCGA-AF-3913.DF1AB72F-80E5-4F91-BA98-623C4D48B50D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).